Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8I9, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8I9-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.
(B) RIGHT PELVIC LYMPH NODES:
Thirteen lymph nodes, no tumor present (0/13).
(C) LEFT PELVIC LYMPH NODES:
One lymph node, no tumor present (0/1).

CCF ICDO-3
Adenocarcinoma, acinar 8140/3
path Adenocarcinoma NOS 8140/3
Site Prostate NOS C619
gW 11/24/13

GROSS DESCRIPTION

- (A) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.
(B) RIGHT PELVIC LYMPH NODES – A pad of adipose tissue (6.0 x 3.4 x 1.0 cm) with eight possible lymph nodes (0.4 x 0.4 cm to 3.8 x 1.0 cm). The specimen is entirely submitted.
SECTION CODE: B1, one possible lymph node; B2, B3, one possible lymph node, sectioned; B4, one possible lymph node sectioned; B5-B10, largest lymph node sectioned; B11, two possible lymph nodes; B12, two possible lymph nodes; B13-B17, remainder of adipose tissue.
(C) LEFT PELVIC LYMPH NODES – A pad of adipose tissue (3.0 x 1.9 x 1.3 cm) with one possible lymph node. The specimen is entirely submitted.
SECTION CODE: C1-C5, one lymph node, sectioned; C6, remainder of adipose tissue.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

T-C4600, M-00110

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(A) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 8 (4+4). (SEE COMMENT)

EXTRAPROSTATIC EXTENSION PRESENT.

FOCAL EXTENSION OF TUMOR TO THE CAUTERIZED MARGIN OF RESECTION CANNOT BE UNEQUIVOCALLY EXCLUDED.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

PERINEURAL AND LYMPHOVASCULAR INVASION PRESENT.

COMMENT

The prostate gland contains two foci of prostatic adenocarcinoma, one in the peripheral zone and one in the transition zone. The dominant tumor focus is located in the right lateral, right posterolateral, right posterior, mid posterior and left posterior peripheral zone. This tumor focus measures 2.5 x 2.0 cm in the largest cross-sectional dimension and it is present in the single cross section of the prostate and extensively in the apex and base. The tumor exhibits extensive extraprostatic extension in the right posterolateral surface of the prostate and right superior neurovascular bundle region. The added length of extraprostatic extension is 18.5 mm. On the right base, focal extension of tumor to the cauterized margin cannot be unequivocally excluded. The second tumor focus is located in the left transition zone. This tumor focus measures 0.8 x 0.3 cm in the largest cross-sectional dimension and it is present in the single cross section of the prostate, focally in the apex and extensively in the base. This tumor focus is of lower histologic grade and confined to the prostate with negative margins.

GROSS DESCRIPTION

(A) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.1 x 3.1 x 3.9 cm, 28.0 grams, post-fixation) has the usual shape. The soft tissue present along the posterolateral aspects of the prostate is abundant and symmetrical. A nodule is palpated on the right side of the prostate. Serial cross-sections after fixation demonstrate an area consistent with tumor in the right side of the single cross-section of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: A1-A4, right seminal vesicle and segment of right vas deferens from the base towards the tip; A5-A7, left seminal vesicle and segment of left vas deferens from the base towards the tip; A8, prostatic base, right border; A9-A12, prostatic base, right posterior border; A13-A20, prostatic base, central portion; A21, prostatic base, left border; A22-A24, prostatic base, left posterior border; A25-A26, apex anterior; A27-A28, apex left; A29-A31, apex posterior; A32-A33, apex right; A34-A37, sections of the single cross-section of the prostate according to the specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in

[page 3 of 3]
[REDACTED]

Specimen Date/Time:

black.

SNOMED CODES

T-92000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

1st or 2nd Primary History		
Reviewed Initials	gfc	

Source: NCI Genomic Data Commons file 3514a125-f116-42b1-8cb7-d12ae88eff87 (TCGA-KK-A8I9.D086A0A1-E06A-4B7E-B158-A5D04BCE06E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).